Somatic mutation profile of tumor specimen TCGA-KD-A5QU-01A (aliquot TCGA-KD-A5QU-01A-11D-A27P-09) from TCGA case TCGA-KD-A5QU, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 41.1 years (15,018 days).
Specimen TCGA-KD-A5QU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4359ff0a-edb1-46c4-b684-8c2bb6e1a6c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KD-A5QU-10A (Blood Derived Normal), aliquot TCGA-KD-A5QU-10A-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a02991cc-dfe5-4c1b-9365-605bd2ede401

The open-access MAF lists 60 somatic variants for this specimen: 50 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 9, Nonsense Mutation 4, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- UBE3B | c.1852C>T p.R618* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as rs746058354, COSV99784492; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALDH1L1 | c.1946C>A p.T649K | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99857523; called by muse, mutect2, varscan2
- ATRX | c.4160C>G p.S1387* | Nonsense Mutation (SNP) | VAF 73/150 reads (49%) | catalogued as COSV64873705; called by muse, mutect2, varscan2
- BRD8 | c.3479G>T p.G1160V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99496977; called by muse, mutect2, varscan2
- C14orf39 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs34082126; called by muse, mutect2, varscan2
- C1QTNF9 | c.626C>T p.T209M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs557592254, COSV59658470; called by mutect2, varscan2
- CEP131 | c.3182C>T p.A1061V (on ENST00000269392 / NM_001319228.2; = p.A1058V on NM_014984.4) | Missense Mutation (SNP) | VAF 40/58 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs774586774, COSV99488389; called by muse, mutect2
- COL19A1 | c.3299C>T p.S1100L | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.172); catalogued as rs148400214; called by muse, mutect2, varscan2
- CROCC | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as COSV100978405; called by muse, mutect2, varscan2
- DNAH2 | c.11032C>T p.L3678F | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1441927485, COSV101209591; called by muse, mutect2, varscan2
- DNAI2 | c.476A>G p.Q159R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV100210070; called by muse, mutect2, varscan2
- DOCK8 | c.4785G>T p.Q1595H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101210077; called by muse, mutect2, varscan2
- DSCAML1 | c.3652G>A p.E1218K (on ENST00000321322; = p.E1158K on NM_020693.4) | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.769); catalogued as COSV100357259; called by muse, mutect2
- EFCAB3 | c.412A>G p.I138V | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV100540492; called by muse, mutect2, varscan2
- EPHA7 | c.2402G>T p.R801M | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100994360, COSV65177462; called by muse, mutect2, varscan2
- EVPL | c.5905G>A p.A1969T | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV101440973; called by muse, mutect2, varscan2
- FCHSD1 | c.1106A>G p.E369G | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV101447615; called by muse, mutect2
- GTPBP8 | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.125); catalogued as COSV99868537; called by muse, mutect2
- HELQ | c.2492C>T p.T831I | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99788136; called by muse, mutect2
- IQCE | c.1961C>G p.A654G | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.221); catalogued as rs780284226, COSV100383744; called by muse, mutect2, varscan2
- KIAA1217 | c.1310A>T p.N437I | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV100287316, COSV56817917; called by muse, mutect2, varscan2
- KLK11 | c.782A>T p.K261M (on ENST00000594768 / NM_144947.3; = p.K229M on NM_006853.3) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100011294; called by muse, mutect2, varscan2
- LHX8 | c.616G>T p.G206W | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV53955858; called by muse, mutect2, varscan2
- LPAR5 | c.950C>A p.A317D | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100321113; called by muse, mutect2, varscan2
- MELTF | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1466792409, COSV99586621; called by muse, mutect2, varscan2
- MTUS2 | c.2259T>A p.Y753* | Nonsense Mutation (SNP) | VAF 44/52 reads (85%) | catalogued as COSV101462067, COSV101462371; called by muse, mutect2, varscan2
- NUFIP1 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 55/67 reads (82%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100998061; called by muse, mutect2, varscan2
- NUTM2F | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs1210582791, COSV99480420; called by muse, mutect2, varscan2
- OR2AG2 | c.682A>G p.M228V | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as rs1224882549, COSV100643181; called by muse, mutect2, varscan2
- OR8S1 | c.395A>G p.Y132C | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100043747; called by muse, mutect2, varscan2
- PARP14 | c.4073G>C p.G1358A | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.194); catalogued as COSV101506351, COSV101506386; called by muse, mutect2
- POLR1G | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV100338341; called by muse, mutect2, varscan2
- PSG1 | c.664C>A p.P222T | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.472); catalogued as rs374973420; called by muse, mutect2, varscan2
- RBM14 | c.1819C>A p.R607S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100036968, COSV59560898; called by muse, mutect2, varscan2
- REV1 | c.1097G>A p.C366Y | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV99301488; called by muse, mutect2
- SETX | c.7612G>C p.D2538H | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1473906430, COSV99810969; called by muse, mutect2, varscan2
- SEZ6L | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs761270884, COSV50666037, COSV50694767; called by muse, mutect2, varscan2
- SLF2 | c.1394C>T p.T465M | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs768453131, COSV53278385; called by muse, mutect2, varscan2
- TGFBR3 | c.941A>C p.K314T | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.06); catalogued as COSV99283680; called by muse, mutect2
- TLN2 | c.1279G>A p.V427I | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs757965110, COSV100170067; called by muse, mutect2, varscan2
- TMEM125 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs756819583, COSV101443218; called by muse, mutect2, varscan2
- TNPO3 | c.2027G>A p.G676E | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.066); catalogued as COSV99603481; called by muse, mutect2, varscan2
- TOPBP1 | c.2881G>A p.V961I | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as COSV99605845; called by muse, mutect2, varscan2
- URB2 | c.3758G>C p.G1253A | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99271913; called by muse, mutect2, varscan2
- UROC1 | c.1105G>T p.A369S | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99332393; called by muse, mutect2, varscan2
- WRAP53 | c.96G>A p.M32I | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as COSV53395934, COSV99455013; called by muse, mutect2, varscan2
- ZNF681 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV101267592; called by muse, mutect2, varscan2
- IGKV3-15 | c.125C>G p.S42C | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- PIWIL3 | c.1814C>A p.P605Q | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PLPP1 | c.764_769del p.S255_K257delins* | Nonsense Mutation (DEL) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- C2orf16 | c.2526A>C p.L842= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs375613150, COSV100821019; called by muse, mutect2, varscan2
- CACNB4 | c.636T>G p.P212= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs1238626923, COSV99139626; called by muse, mutect2, varscan2
- DERA | c.693G>A p.P231= | Silent (SNP) | VAF 31/37 reads (84%) | catalogued as rs200029512, COSV101397518; called by muse, mutect2, varscan2
- DNAH5 | c.9975C>T p.C3325= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs771715883, COSV99451714; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ERBB4 | c.1329C>A p.T443= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV99632934; called by muse, mutect2, varscan2
- KLF4 | c.1074G>A p.P358= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV101012769; called by muse, mutect2, varscan2
- MPP1 | c.111G>A p.S37= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs1557267851, COSV101053757, COSV104423488; called by muse, mutect2, varscan2
- SLC9A4 | c.2082C>T p.S694= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs369230553; called by muse, mutect2, varscan2
- UMPS | c.784C>T p.L262= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99229317; called by muse, varscan2
- MIR1297 | n.8C>T | RNA (SNP) | VAF 15/15 reads (100%) | catalogued as rs777503320; called by muse, mutect2, varscan2
